Surgical pathology report (de-identified scan), TCGA case TCGA-HU-A4H2, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-A4H2-01A (Primary Tumor).

[page 1 of 2]
Specimen: A. Distal margin (FS), B. Stomach and lymph node,
C. Distal margin.

DIAGNOSIS:

A-C) Stomach, distal gastrectomy:

- ADVANCED GASTRIC CARCINOMA, SINGLE, LOWER THIRD OF STOMACH,
ANTRUM ALONG LESSER CURVATURE, AGC BORRMANN TYPE 3,
TUBULAR ADENOCARCINOMA, MODERATELY DIFFERENTIATED WITH SIGNET
RING CELL COMPONENT, MIXED TYPE, 7.5 x 5 x 1.8 cm,
with 1) invasion to subserosa.

2) INVOLVEMENT OF DISTAL RESECTION MARGIN BY A
FOCUS SIGNET RING CELL CARCINOMA IN SUBSEROA.

3) no involvement of proximal resection margin
(distance to margin: proximal, 6.5 cm).

4) LYMPHOVASCULAR INVASION: PRESENT.

5) PERINEURAL INVASION: PRESENT.

6) METASTASIS IN 34 OF 65 LYMPH NODES (34/65)
(largest metastatic tumor size: 8 mm,

with / without extranodal extension: 1.5 mm).

1CD-0-3
adenocarcinoma, tubular 8211/3
Site: Stomach, antrum C16.3

hw
9/27/12

<Addendum>

Final diagnosis: Stomach Intestinal Adenocarcinoma, Tubular Type

per clarification by TSS -
Not mixed.

Dx discrepancy form attached
10/9/12
hw

NOT mixed - per TSS

Diagnosis Discrepancy (Mixed Signet Ring)		
HPA Discrepancy		
Reviewed Initials:		

hw
9/26/12

[page 2 of 2]
TCGA Pathologic Diagnosis Discrepancy Form

Tissue Source Site (TSS): Stomach adenocarcinoma

Completed By _____

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Stomach Tubular Adenocarcinoma, w/Signet Ring Component Mixed	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF	Stomach Intestinal Adenocarcinoma, Tubular Type	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	In the original pathology report, (for the whole resected specimen) this tumor is described as containing signet ring cell carcinoma component. Review of TCGA sample top slide identified that this tumor is solely composed of an stomach adenocarcinoma, tubular type and the addendum was created as such.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 89a8cdab-eabf-418a-bf47-c4fa0c10f143 (TCGA-HU-A4H2.2E830971-490D-4AE0-A78F-3885E0E54E96.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).